Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3FK, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3FK-01A (Primary Tumor).

[page 1 of 3]
ORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[Redacted]	Accession #:	[Redacted]
MRN:	[Redacted]	Collected:	[Redacted]
DOB:	[Redacted]	Received:	[Redacted]
Gender:	[Redacted]	Reported:	[Redacted]
HCN:	[Redacted]		
Ordering MD:	[Redacted]		
Copy To:	[Redacted]		
Service:	[Redacted]		
Visit #:	[Redacted]		
Location:	[Redacted]		
Facility:	[Redacted]		

Specimen(s) Received

1. Lymph-Node: left paratracheal node
2. Lymph node: Left level four nodes neck
3. Parathyroid: Right upper parathyroid QS
4. Thyroid: total thyroid stitch marks upper pole

1CB-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C93.9 W 11/22/14

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 3 of 3 (left paratracheal) biopsy
2. Metastatic papillary thyroid carcinoma: Lymph node, 1 of 6 (left neck level four), dissection specimen
3. No pathological diagnosis: Parathyroid (right upper) biopsy
4. Multifocal papillary carcinoma, dominant 1.2 cm, classic variant, isthmus: Thyroid
Metastatic papillary thyroid carcinoma: Lymph nodes, 13 of 16
No pathological diagnosis: Parathyroid, left
-Total thyroidectomy specimen

Synoptic Data

Procedure:	Total thyroidectomy with central compartment dissection
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.0 cm
	1.8 cm
	1.1 cm
	Left lobe:
	4.5 cm
	2.1 cm
	1.4 cm
	Isthmus +/- pyramidal lobe:
	2.7 cm
	0.6 cm
	0.7 cm
	Central compartment:

Reviewed:	W 11/22/14	11/22/14

[page 2 of 3]
Surgical Pathology Consultation Report

1.0 cm
1.0 cm
0.5 cm
Specimen Weight: 15.8 g
Tumor Focality: Multifocal, bilateral
Multifocal, midline (isthmus)

----- DOMINANT TUMOR -----
Tumor Laterality: Isthmus
Tumor Size: Greatest dimension: 1.2cm
Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.3mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Indeterminate
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.0cm
Histologic Type: Papillary carcinoma, classical (usual)
Classical (papillary) architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Cannot be assessed
Lymph-Vascular Invasion: Indeterminate
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT1: Tumor size 2 cm or less, limited to thyroid
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior
mediastinal lymph nodes
Number of regional lymph nodes examined: 25
Number of regional lymph nodes involved: 17
Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Thyroiditis, palpation
Parathyroid gland(s), within normal limits
Other: multiple Papillary microcarcinomas, left and right

*Pathologic Staging is based on AJCC/UICC TNM,

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "Lymph node: Left paratracheal node" consists of a piece of tissue that measures 1.5 x 0.6 x 0.2 cm and contains 3 nodules ranging from 0.1 to 0.5 cm.
1A submitted in toto

[page 3 of 3]
Surgical Pathology Consultation Report

2. The specimen labeled with the patient's name and as "Lymph node: Left neck level 4 nodes" consists of a piece of tissue that measures 2.0 x 0.5 x 0.6 cm and contains multiple nodules ranging from 0.1 to 0.5 cm.
2A-B submitted in toto

3. The specimen labeled with the patient's name and as "Parathyroid: Right Upper Parathyroid QS" contains a piece of tissue that measures 0.3 x 0.2 x 0.1 cm and weighs 0.002 g. It is frozen for intraoperative consultation.
3A frozen tissue resubmitted

4. The specimen labeled with the patient's name and as "Total thyroid stitch marks upper right pole" consists of a thyroid gland that is received oriented with a suture and weighs 15.8 g. The right lobe measures 5.0 cm SI x 1.8 cm ML x 1.1 cm AP, the left lobe measures 4.5 cm SI x 2.1 cm ML x 1.4 cm AP and the isthmus measures 2.7 cm SI x 0.6 cm ML x 0.7 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands are identified grossly. Extending from the right lower pole is a portion of soft tissue measuring 1.0 x 1.0 x 0.5 cm. Within this are several possible lymph nodes. The external surface is painted with blue ink. The isthmus and left lobe contain multiple delineated nodules that measure up to 1.2 cm SI x 1.0 cm ML x 0.7 cm AP. The larger nodules are present in the isthmus and the upper pole of the left lobe. The remainder of the thyroid tissue is red-brown and unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

4A-F right lobe, superior to inferior

4G-H isthmus

4I-N left lobe, superior to inferior

4O-P soft tissue with lymph nodes from right lower pole

Quick Section Diagnosis

QS3A:- Parathyroid tissue.

Source: NCI Genomic Data Commons file bd0df57c-34bc-4726-8228-1bc4c0fd7bc7 (TCGA-EM-A3FK.A1ED1E7A-FCA0-4F32-9687-88855105E262.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).